Somatic mutation profile of tumor specimen TCGA-CG-4465-01A (aliquot TCGA-CG-4465-01A-01D-1158-08) from TCGA case TCGA-CG-4465, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 69.1 years (25,233 days).
Specimen TCGA-CG-4465-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 167ed969-5174-4511-b753-23b62d4d2239.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4465-10A (Blood Derived Normal), aliquot TCGA-CG-4465-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/354c131d-9f78-45a9-87fc-5055b2f87907

The open-access MAF lists 736 somatic variants for this specimen: 572 protein-altering or splice-affecting, 146 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 365, Silent 146, Frame Shift Del 145, Frame Shift Ins 25, Nonsense Mutation 20, Intron 9, Splice Site 8, In Frame Del 5, RNA 4, Splice Region 3, 5'UTR 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 33/126 reads (26%) | catalogued as rs1085307154, CM085286, COSV65809003; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as rs868369541, CM043451, COSV65809006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.1502del p.P501Lfs*57 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | catalogued as rs1085307855; ClinVar: pathogenic; called by mutect2, varscan2
- CWC27 | c.1002del p.V335* | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs752159903; ClinVar: pathogenic; called by mutect2, varscan2
- DBT | c.360del p.K120Nfs*6 | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | catalogued as rs398123668; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- DSG1 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | catalogued as rs568609861, COSV57134949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAH | c.615del p.F205Lfs*2 | Frame Shift Del (DEL) | VAF 46/166 reads (28%) | catalogued as rs1057517084; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- IL7R | c.361dup p.I121Nfs*8 | Frame Shift Ins (INS) | VAF 34/112 reads (30%) | catalogued as rs869312857; ClinVar: pathogenic; called by mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- RHOA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 66/124 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 100/303 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520413, CM102583, COSV51839321; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT3 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 81/238 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs747639500, COSV52882933, COSV52884030, COSV52885662; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 52/130 reads (40%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCC4 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as rs1246870484, COSV65310949; called by muse, mutect2, varscan2
- ABCC8 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs774689517, COSV56849692; called by muse, mutect2, varscan2
- ACAP1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs779701618, COSV50135522; called by muse, mutect2, varscan2
- ACTRT1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 117/462 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV64419273; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 134/205 reads (65%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2A | c.1446G>A p.M482I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV54021645; called by muse, mutect2, varscan2
- ADAMTS9 | c.4048C>T p.R1350W | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758184611, COSV55780071; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs202037366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY7 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs746976575, COSV54266306; called by muse, mutect2, varscan2
- ADGRV1 | c.2530G>T p.A844S | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV67984167; called by muse, mutect2
- ADIPOR1 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs1485692750, COSV61851133; called by muse, mutect2, varscan2
- AGRN | c.2255-1G>T p.X752_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | catalogued as COSV65069255; called by muse, mutect2, varscan2
- AHCYL2 | c.695G>A p.C232Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV61486828; called by muse, mutect2, varscan2
- AHSA1 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.678); catalogued as COSV53631792; called by muse, mutect2, varscan2
- AK5 | c.1517C>A p.P506H (on ENST00000354567 / NM_174858.3; = p.P480H on NM_012093.4) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV60971875; called by muse, mutect2, varscan2
- AKAP11 | c.1610del p.N537Ifs*8 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | catalogued as rs764225198; called by mutect2, pindel, varscan2
- ALDH1B1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs369090946, COSV66619607; called by muse, mutect2, varscan2
- ALX3 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776967754, COSV63928742; called by muse, mutect2, varscan2
- AMER3 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV58466444; called by muse, mutect2, varscan2
- AMPD3 | c.112C>A p.L38M (on ENST00000396553 / NM_001025389.2; = p.L47M on NM_000480.3) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV67330786; called by muse, mutect2, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 120/371 reads (32%) | catalogued as rs370637835; called by mutect2, varscan2
- ANK3 | c.3155C>T p.A1052V (on ENST00000280772 / NM_001320874.2; = p.A186V on NM_001149.3) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV55055758; called by muse, mutect2, varscan2
- ANKRD50 | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs747168116, COSV72385459; called by muse, mutect2, varscan2
- ANKRD52 | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV57284022; called by muse, mutect2
- ANKS3 | c.1158A>C p.Q386H | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58508790; called by muse, mutect2
- APC | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs762117133, COSV57340912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEH | c.1527del p.X509_splice | Splice Site (DEL) | VAF 64/208 reads (31%) | catalogued as rs1255876232; called by mutect2, pindel, varscan2
- APOOL | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV64271595; called by muse, mutect2, varscan2
- ARFGEF3 | c.4780A>T p.T1594S | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.03); catalogued as COSV52456331; called by muse, mutect2, varscan2
- ARHGEF11 | c.4447G>A p.A1483T | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1391722474, COSV59354095; called by muse, mutect2, varscan2
- ARHGEF19 | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); catalogued as COSV54616397; called by muse, mutect2, varscan2
- ARID1A | c.2296del p.Q766Sfs*67 | Frame Shift Del (DEL) | VAF 48/150 reads (32%) | catalogued as COSV61372766; called by mutect2, pindel, varscan2
- ARID1B | c.3809G>T p.G1270V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV51659839; called by muse, mutect2, varscan2
- ARMC6 | c.1051C>A p.L351M (on ENST00000392336; = p.L326M on NM_033415.4) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as COSV54181464; called by muse, mutect2, varscan2
- ASCC2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs982302701, COSV57073368; called by muse, mutect2, varscan2
- ASPHD1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV58099125; called by muse, mutect2, varscan2
- ATP13A2 | c.3206C>T p.A1069V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.277); catalogued as rs764988645, COSV58700082; called by muse, mutect2, varscan2
- ATP13A5 | c.2469del p.F823Lfs*19 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | catalogued as rs1441693985; called by mutect2, pindel, varscan2
- ATP1A3 | c.3013G>A p.D1005N (on ENST00000545399 / NM_001256214.2; = p.D992N on NM_152296.5) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs606231447, CM127803, COSV57487156; called by muse, mutect2, varscan2
- ATP1A4 | c.1445del p.N482Tfs*31 | Frame Shift Del (DEL) | VAF 29/212 reads (14%) | catalogued as COSV63626067; called by mutect2, pindel, varscan2
- ATP1B4 | c.443G>T p.R148L (on ENST00000218008 / NM_001142447.3; = p.R144L on NM_012069.5) | Missense Mutation (SNP) | VAF 164/635 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV54312269, COSV54315433; called by muse, mutect2, varscan2
- ATP2B3 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782151825, COSV54845659; called by muse, mutect2, varscan2
- ATP6V0B | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV52543357; called by muse, mutect2, varscan2
- ATP8B2 | c.1147C>T p.R383C (on ENST00000672630; = p.R350C on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs772607479, COSV59245833; called by muse, mutect2, varscan2
- ATP9A | c.2998G>A p.E1000K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as rs571946490, COSV58765920, COSV58767865; called by muse, mutect2, varscan2
- ATP9A | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58765927; called by muse, mutect2, varscan2
- ATXN2L | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs750956235, COSV57369359; called by muse, mutect2, varscan2
- AVIL | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs1382559192, COSV57681634, COSV99142134; called by muse, mutect2, varscan2
- AXIN2 | c.2011del p.R671Afs*18 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as COSV61055329; called by mutect2, pindel, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs771098505; called by mutect2, varscan2
- BAZ2A | c.4544T>C p.L1515P | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51635938; called by muse, mutect2, varscan2
- BMP6 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.398); catalogued as COSV51664671; called by muse, mutect2, varscan2
- BMPR1B | c.76dup p.R26Pfs*8 | Frame Shift Ins (INS) | VAF 30/104 reads (29%) | catalogued as rs1271170297; called by mutect2, pindel, varscan2
- BRAF | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs547693139, COSV56159745; called by muse, mutect2, varscan2
- BRINP1 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs745883942, COSV56315483; called by muse, mutect2, varscan2
- BUB1 | c.2070G>T p.E690D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV57063253; called by muse, mutect2, varscan2
- BZW1 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.045); catalogued as COSV63349675; called by muse, mutect2, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs751388819; called by mutect2, varscan2
- C2orf16 | c.4117C>T p.R1373W | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs376579967; called by muse, mutect2, varscan2
- C4orf17 | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV58512251; called by muse, mutect2, varscan2
- C9orf129 | n.729+1G>A | Splice Site (SNP) | VAF 15/44 reads (34%) | catalogued as COSV64882442; called by muse, mutect2, varscan2
- C9orf78 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 98/350 reads (28%) | catalogued as rs1404733018, COSV65217418; called by muse, mutect2, varscan2
- CACNA2D1 | c.3114T>C p.S1038= (on ENST00000356253 / NM_001366867.1; = p.S1026= on NM_000722.4) | Splice Region (SNP) | VAF 22/74 reads (30%) | catalogued as rs772699849, COSV100666370; called by muse, mutect2, varscan2
- CACNA2D3 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1014738187, COSV55534515; called by muse, mutect2, varscan2
- CACNG3 | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV50067421; called by muse, mutect2, varscan2
- CAMSAP3 | c.3512C>T p.A1171V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs771683691, COSV50333545; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs745547658; called by mutect2, varscan2
- CASP8AP2 | c.3390del p.K1130Nfs*6 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs768812342; called by mutect2, varscan2
- CCDC122 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs1349304691, COSV55709276; called by muse, mutect2, varscan2
- CCDC178 | c.1151del p.N384Mfs*13 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as rs749875431; called by mutect2, pindel, varscan2
- CCDC39 | c.1342C>G p.Q448E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV56483113; called by muse, mutect2, varscan2
- CCDC40 | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs369512832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC66 | c.619dup p.T207Nfs*2 (on ENST00000394672 / NM_001353147.1; = p.T173Nfs*2 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 17/62 reads (27%) | catalogued as rs1247408644; called by mutect2, varscan2
- CD109 | c.3980C>A p.P1327H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV54648768; called by muse, mutect2, varscan2
- CD1D | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as COSV63808922; called by muse, mutect2, varscan2
- CD22 | c.1516dup p.R506Pfs*25 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | catalogued as rs763207241; called by mutect2, pindel, varscan2
- CDC14A | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV60557676; called by muse, mutect2, varscan2
- CDK15 | c.890A>G p.Q297R (on ENST00000652192 / NM_001366386.2; = p.Q246R on NM_139158.2) | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.63); catalogued as COSV53633855; called by muse, mutect2, varscan2
- CENPF | c.8652A>T p.Q2884H | Missense Mutation (SNP) | VAF 94/283 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65274576; called by muse, mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | catalogued as rs769310263; called by mutect2, pindel, varscan2
- CEP192 | c.3005C>T p.T1002M | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs142411472; called by muse, mutect2, varscan2
- CEP250 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778255060, COSV61169756; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 65/198 reads (33%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP97 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs145086802; called by muse, mutect2, varscan2
- CEPT1 | c.1015A>G p.M339V | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs757785358, COSV62959042; called by muse, mutect2, varscan2
- CES2 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV57696763; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 46/163 reads (28%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP65 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485655661, COSV58560433; called by muse, mutect2, varscan2
- CFAP69 | c.2745del p.K915Nfs*12 | Frame Shift Del (DEL) | VAF 57/187 reads (30%) | catalogued as COSV100290203; called by mutect2, pindel, varscan2
- CFHR2 | c.444A>C p.K148N | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV66380994; called by muse, mutect2, varscan2
- CHD4 | c.3491G>A p.R1164H (on ENST00000357008 / NM_001363606.2; = p.R1177H on NM_001273.5) | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV58895948; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA7 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs573369306, COSV60970070; called by mutect2, varscan2
- CIC | c.2860C>T p.Q954* | Nonsense Mutation (SNP) | VAF 35/137 reads (26%) | catalogued as COSV50563385; called by muse, mutect2, varscan2
- CLPX | c.1046A>C p.K349T | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100269396; called by muse, mutect2
- CMTM6 | c.316-1G>T p.X106_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV52750102; called by muse, mutect2, varscan2
- CNOT1 | c.6829C>A p.P2277T | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54699950; called by muse, mutect2, varscan2
- CNTLN | c.1592T>C p.L531P | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV52076217; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs374805044; called by mutect2, varscan2
- COL11A2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.689); catalogued as rs970615748, COSV59494221; called by muse, mutect2, varscan2
- COL4A3 | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.32); catalogued as rs771403339, COSV67415202; called by muse, mutect2, varscan2
- CORO2A | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs894748322, COSV59663064; called by muse, mutect2, varscan2
- CPNE4 | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV70189928, COSV70193684; called by muse, mutect2, varscan2
- CPXM2 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV53860985; called by muse, mutect2, varscan2
- CRYGC | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs1469741282, COSV56408965; called by muse, mutect2, varscan2
- CSNK1G3 | c.145del p.I49Lfs*11 | Frame Shift Del (DEL) | VAF 51/165 reads (31%) | catalogued as rs775129818, COSV62054115, COSV62057434; called by mutect2, varscan2
- CTDP1 | c.1721A>C p.Q574P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as COSV50002831; called by muse, mutect2, varscan2
- CTNNA2 | c.1259T>C p.V420A | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as COSV100560060, COSV58135013, COSV58149761; called by muse, mutect2, varscan2
- CTNND1 | c.2044G>A p.E682K (on ENST00000399050 / NM_001085458.2; = p.E676K on NM_001331.3) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV62383258; called by muse, mutect2, varscan2
- CUL9 | c.5866C>T p.P1956S | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV52727922; called by muse, mutect2, varscan2
- CUX1 | c.4429C>A p.R1477S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV52897836; called by muse, mutect2
- CXorf56 | c.39C>G p.D13E | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57438118; called by muse, mutect2, varscan2
- CYP4X1 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as COSV64150560; called by muse, mutect2, varscan2
- CYP7B1 | c.760T>G p.L254V | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV59587283; called by muse, mutect2, varscan2
- DACH2 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64167535; called by muse, mutect2, varscan2
- DCAF4L2 | c.895T>G p.L299V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV60478253; called by muse, mutect2
- DDR2 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 97/303 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63370736; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 56/152 reads (37%) | catalogued as rs766714372; called by mutect2, varscan2
- DGKK | c.2064G>T p.K688N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1295795745, COSV65707219; called by muse, mutect2, varscan2
- DIS3 | c.2032del p.I678Ffs*59 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | catalogued as rs771690280; called by mutect2, varscan2
- DIS3L2 | c.2563G>T p.A855S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV56053437; called by muse, mutect2, varscan2
- DLG5 | c.5538G>T p.K1846N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64947783; called by muse, mutect2, varscan2
- DLX5 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV56032290; called by muse, mutect2, varscan2
- DNAH10 | c.772C>T p.R258W (on ENST00000409039; = p.R197W on NM_207437.3) | Missense Mutation (SNP) | VAF 135/421 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs144283758, COSV68991666; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH9 | c.5206G>T p.A1736S | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as COSV52347191; called by muse, mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 17/132 reads (13%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DOCK2 | c.4279C>T p.P1427S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.6); catalogued as COSV56955670; called by muse, mutect2, varscan2
- DOCK3 | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56518210; called by muse, mutect2, varscan2
- DPYSL3 | c.1487G>T p.R496M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV58326394; called by muse, mutect2, varscan2
- DYSF | c.3662C>T p.P1221L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs368556029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECE1 | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243553784, COSV51664065; called by muse, mutect2, varscan2
- ECHDC2 | c.697C>T p.P233S (on ENST00000371522 / NM_001198961.2; = p.P202S on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV100597403, COSV64300920; called by muse, mutect2, varscan2
- ECT2L | c.2006T>C p.V669A | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.313); catalogued as rs754340335, COSV62884118; called by muse, mutect2, varscan2
- EDIL3 | c.1118A>G p.D373G | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV56894366; called by muse, mutect2, varscan2
- EDIL3 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56894380; called by muse, mutect2, varscan2
- EEF1D | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52784487; called by muse, mutect2, varscan2
- EFS | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.424); catalogued as COSV53732148; called by muse, mutect2, varscan2
- ELF5 | c.698T>C p.L233P (on ENST00000312319 / NM_198381.2; = p.L223P on NM_001422.4) | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56628752; called by muse, mutect2, varscan2
- ELMO1 | c.84dup p.P29Tfs*11 | Frame Shift Ins (INS) | VAF 43/206 reads (21%) | catalogued as rs766966664; called by mutect2, pindel, varscan2
- EP400 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs111485547; called by muse, mutect2
- EPHB1 | c.1139T>G p.V380G | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.64); catalogued as COSV67660066; called by muse, mutect2, varscan2
- EPHX1 | c.400del p.Q134Sfs*12 | Frame Shift Del (DEL) | VAF 89/284 reads (31%) | catalogued as rs756407271; called by mutect2, varscan2
- EPS8L3 | c.221A>C p.D74A | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV62609360; called by muse, mutect2
- ERN1 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as rs376936066; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs775950025; called by mutect2, varscan2
- F8 | c.6203A>G p.K2068R | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV64270562, COSV64272755; called by muse, mutect2, varscan2
- F8 | c.1322A>T p.K441M | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV64272768; called by muse, mutect2, varscan2
- FAM47A | c.1770C>G p.S590R | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV60496154; called by muse, mutect2, varscan2
- FAM81B | c.293A>T p.K98M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51982507; called by muse, mutect2, varscan2
- FAM98B | c.938T>C p.I313T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV67022773; called by muse, mutect2, varscan2
- FANCI | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55526424; called by muse, mutect2
- FARP1 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60336075; called by muse, mutect2, varscan2
- FAT4 | c.5363G>A p.R1788H | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs200898075, COSV58670988; called by muse, mutect2, varscan2
- FBXW11 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as rs1199148006, COSV51608710; called by muse, mutect2, varscan2
- FBXW5 | c.1228C>A p.L410M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56402803; called by muse, mutect2, varscan2
- FCRL5 | c.2397dup p.S800Lfs*21 | Frame Shift Ins (INS) | VAF 35/145 reads (24%) | catalogued as rs761392473; called by mutect2, pindel, varscan2
- FGFR2 | c.2193A>G p.E731= | Splice Region (SNP) | VAF 126/382 reads (33%) | catalogued as COSV60645929; called by muse, mutect2, varscan2
- FLII | c.1399C>G p.R467G | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs767337540, COSV58944657; called by muse, mutect2, varscan2
- FLNA | c.7900del p.D2634Tfs*71 (on ENST00000369850 / NM_001110556.2; = p.D2626Tfs*71 on NM_001456.3) | Frame Shift Del (DEL) | VAF 42/134 reads (31%) | catalogued as COSV61046828; called by mutect2, pindel, varscan2
- FTSJ3 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs1217008899, COSV59562366; called by muse, mutect2, varscan2
- FUNDC2 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs1245068274, COSV65670841; called by muse, mutect2, varscan2
- GABRA6 | c.79T>C p.F27L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50880334, COSV50881677, COSV50882038; called by muse, mutect2, varscan2
- GALNT13 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV67218941; called by muse, mutect2, varscan2
- GDF6 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54624691; called by muse, mutect2, varscan2
- GJB3 | c.136del p.D46Mfs*222 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as COSV64904641; called by mutect2, pindel, varscan2
- GLB1L2 | c.1354C>A p.Q452K | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV60277982, COSV60278404; called by muse, mutect2, varscan2
- GLI1 | c.250T>C p.S84P | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1364213000, COSV57361214; called by muse, mutect2, varscan2
- GLMP | c.547A>G p.R183G | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55294929; called by muse, mutect2, varscan2
- GLRB | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52416345; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAS | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV58333733; called by muse, mutect2, varscan2
- GOLGA4 | c.4098del p.V1367Lfs*10 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as rs768760517; called by mutect2, varscan2
- GOSR2 | c.344G>A p.R115Q (on ENST00000393456 / NM_001321134.1; = p.R180Q on NM_004287.5) | Missense Mutation (SNP) | VAF 141/480 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs1348639194, COSV56662251; called by muse, mutect2, varscan2
- GPD1 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV56547911; called by muse, mutect2, varscan2
- GPRASP2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV59991066; called by muse, mutect2, varscan2
- GRAMD4 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV63030124; called by muse, mutect2
- GRIK3 | c.2512G>A p.V838M | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV66139040; called by muse, mutect2, varscan2
- GRP | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV56879434; called by muse, mutect2, varscan2
- GSDMC | c.722A>G p.E241G | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.103); catalogued as COSV52695119; called by muse, mutect2, varscan2
- GYG2 | c.954dup p.P319Afs*14 | Frame Shift Ins (INS) | VAF 9/57 reads (16%) | catalogued as rs770047512; called by mutect2, varscan2
- HACD2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.259); catalogued as COSV67322555; called by muse, mutect2, varscan2
- HBB | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs33948615, CM850014, CM870034, CM993614, COSV58942280; ClinVar: other; called by muse, mutect2, varscan2
- HDAC7 | c.1993C>T p.R665W (on ENST00000427332; = p.R704W on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50345329; called by muse, mutect2, varscan2
- HEATR1 | c.5119_5121del p.E1707del | In Frame Del (DEL) | VAF 20/162 reads (12%) | catalogued as rs781364360; called by pindel, varscan2
- HMCN2 | c.2270G>T p.R757M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV70280541; called by muse, mutect2, varscan2
- HNRNPDL | c.568G>T p.G190* | Nonsense Mutation (SNP) | VAF 61/169 reads (36%) | catalogued as COSV55022534; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs755016625; called by mutect2, varscan2
- HR | c.2074T>C p.C692R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57191826; called by muse, mutect2, varscan2
- HRNR | c.8060G>C p.R2687P | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV64257228; called by muse, mutect2, varscan2
- HS3ST5 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.18); catalogued as rs750723182, COSV100450662, COSV57139218; called by muse, mutect2, varscan2
- HS6ST2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV63712623; called by muse, mutect2, varscan2
- HSPG2 | c.11924C>A p.P3975H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60828137; called by muse, mutect2
- HSPG2 | c.7402G>A p.V2468I | Missense Mutation (SNP) | VAF 100/301 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV65971095; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 21/88 reads (24%) | catalogued as rs747841314; called by mutect2, varscan2
- ICAM2 | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV56743398; called by muse, mutect2, varscan2
- ICE1 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56823432; called by muse, mutect2, varscan2
- IFT140 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as rs1159315989, COSV68488139; called by muse, mutect2
- IGFBP3 | c.419C>A p.S140* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV51872336; called by muse, mutect2, varscan2
- IKBKE | c.2114A>G p.E705G | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV65623229; called by muse, mutect2, varscan2
- ILK | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as COSV54990386; called by muse, mutect2, varscan2
- IMP4 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 59/166 reads (36%) | catalogued as rs759130693, COSV52091647; called by muse, mutect2, varscan2
- INO80D | c.2759C>T p.T920M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV68958778; called by muse, mutect2, varscan2
- INSYN2A | c.564G>T p.L188F | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV54738176; called by muse, mutect2, varscan2
- IPO9 | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778640930, COSV64233540; called by muse, mutect2, varscan2
- IQCN | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs372896613; called by muse, mutect2, varscan2
- IQGAP1 | c.4640A>G p.K1547R | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.38); catalogued as COSV51582391, COSV51584906; called by muse, mutect2, varscan2
- ITGB1 | c.786+2T>C p.X262_splice | Splice Site (SNP) | VAF 68/186 reads (37%) | catalogued as COSV56481228; called by muse, mutect2, varscan2
- JADE2 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs554945499, COSV50915087; called by muse, mutect2, varscan2
- JADE2 | c.1650G>A p.W550* | Nonsense Mutation (SNP) | VAF 40/153 reads (26%) | catalogued as COSV50915171; called by muse, mutect2, varscan2
- JAKMIP1 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 74/284 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV51529156; called by muse, mutect2, varscan2
- JAML | c.116T>C p.L39P (on ENST00000356289 / NM_001098526.2; = p.L29P on NM_153206.3) | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52627462; called by muse, mutect2, varscan2
- KCNJ12 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140486656, COSV59164365; called by muse, mutect2
- KCNN4 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV53455320; called by muse, mutect2, varscan2
- KCNS1 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV60260047; called by muse, mutect2
- KIAA0895L | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs767927390, COSV51782786; called by muse, mutect2, varscan2
- KIAA1109 | c.4770del p.K1590Nfs*11 | Frame Shift Del (DEL) | VAF 11/100 reads (11%) | catalogued as rs779140281, COSV52689741; called by mutect2, varscan2
- KIF13A | c.3345dup p.V1116Sfs*4 | Frame Shift Ins (INS) | VAF 65/166 reads (39%) | catalogued as rs1346755993; called by mutect2, varscan2
- KIF1B | c.1832G>A p.R611K (on ENST00000377086 / NM_001365952.1; = p.R565K on NM_015074.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.044); catalogued as COSV55808006; called by mutect2, varscan2
- KIF1C | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 139/388 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs780907252, COSV57903919; called by muse, mutect2, varscan2
- KLHL17 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs761976545, COSV58531610; called by muse, mutect2, varscan2
- KLHL34 | c.1790T>A p.L597H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV65279174; called by muse, mutect2, varscan2
- KLHL36 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs757436138, COSV50718774; called by muse, mutect2, varscan2
- KLK13 | c.392A>G p.Q131R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV50067039; called by muse, mutect2
- KMT2A | c.4355G>T p.C1452F | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63285266; called by muse, mutect2, varscan2
- KMT2C | c.8957G>A p.G2986D | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs755062207, COSV51434351; called by muse, mutect2, varscan2
- KNDC1 | c.3716A>C p.K1239T | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV58835969; called by muse, mutect2, varscan2
- KNG1 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs369801278; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 52/151 reads (34%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KPNB1 | c.2052C>A p.N684K | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51596656; called by muse, mutect2, varscan2
- KRT73 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59838966; called by muse, mutect2, varscan2
- KRT8 | c.284T>A p.I95N | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV53177058; called by muse, mutect2, varscan2
- KYNU | c.794G>A p.W265* | Nonsense Mutation (SNP) | VAF 65/218 reads (30%) | catalogued as COSV51582663; called by muse, mutect2, varscan2
- LAMB3 | c.1858C>A p.L620M | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61916594; called by muse, mutect2, varscan2
- LAMB3 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61916601; called by muse, mutect2, varscan2
- LARP4 | c.1118del p.N373Ifs*3 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | catalogued as rs1179425728; called by mutect2, pindel, varscan2
- LIPC | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1392139947, COSV54422222; called by muse, mutect2
- LMTK3 | c.3586del p.D1196Tfs*120 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as COSV54316473; called by mutect2, pindel
- LMX1B | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62739353; called by muse, mutect2, varscan2
- LMX1B | c.986G>A p.S329N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV62739365; called by muse, mutect2, varscan2
- LPCAT1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs771913207, COSV52037199; called by muse, mutect2, varscan2
- LPIN3 | c.335dup p.L113Sfs*15 | Frame Shift Ins (INS) | VAF 22/78 reads (28%) | catalogued as rs756955559; called by mutect2, varscan2
- LRRC14 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as rs1236797902, COSV52879115; called by muse, mutect2, varscan2
- LTBP3 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57240203; called by muse, mutect2, varscan2
- LTBP4 | c.3268G>A p.V1090M (on ENST00000308370 / NM_001042544.1; = p.V1053M on NM_003573.2) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs559351690, COSV52580549; called by muse, mutect2, varscan2
- LYVE1 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 113/399 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56282536; called by muse, mutect2, varscan2
- LZIC | c.570del p.K190Nfs*16 | Frame Shift Del (DEL) | VAF 62/481 reads (13%) | catalogued as rs753028254; called by mutect2, pindel, varscan2
- MAN2B1 | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV55471717; called by muse, mutect2, varscan2
- MAP1B | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57097506, COSV57098177; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3478G>T p.G1160C | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51599842, COSV51600283; called by muse, mutect2, varscan2
- MARVELD3 | c.948del p.Y317Tfs*45 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs747980715, COSV51704302; called by mutect2, varscan2
- MAST4 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.343); catalogued as rs775063342, COSV68236532; called by muse, mutect2
- MBP | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs747162845, COSV63557540; called by muse, mutect2, varscan2
- MDC1 | c.5741del p.G1914Efs*57 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | catalogued as rs1344945241; called by mutect2, pindel, varscan2
- MED7 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53850066; called by muse, mutect2, varscan2
- MGAT2 | c.635A>G p.N212S | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779133498, COSV53565953; called by muse, mutect2, varscan2
- MIOS | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60768180; called by muse, mutect2, varscan2
- MN1 | c.130C>G p.P44A | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs760446763, COSV100179747, COSV56556666; called by mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 52/114 reads (46%) | catalogued as rs755830405; called by mutect2, varscan2
- MORN4 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as rs752189786, COSV56729737; called by muse, mutect2, varscan2
- MOS | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1040478986, COSV61336097; called by muse, mutect2, varscan2
- MPG | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as COSV54738103; called by muse, mutect2, varscan2
- MPP2 | c.1609G>A p.G537R (on ENST00000461854 / NM_001278372.2; = p.G513R on NM_005374.5) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as COSV52235443; called by muse, mutect2, varscan2
- MRGPRE | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs577257006, COSV67745696; called by muse, mutect2, varscan2
- MRPS5 | c.336del p.G113Efs*14 | Frame Shift Del (DEL) | VAF 68/231 reads (29%) | catalogued as rs1558684714; called by mutect2, pindel, varscan2
- MTDH | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60343718; called by muse, mutect2, varscan2
- MTF2 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1046801, COSV64770333; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs767880823; called by mutect2, varscan2
- MTPAP | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53932641; called by muse, mutect2, varscan2
- MYH14 | c.4403G>A p.R1468H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs760481743, COSV51810914; called by muse, mutect2, varscan2
- MYO1A | c.520del p.L174Sfs*15 | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | catalogued as COSV100270847; called by mutect2, pindel, varscan2
- MYOF | c.4489T>C p.F1497L | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV63703448; called by muse, mutect2, varscan2
- NAALADL2 | c.1549C>A p.L517I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69155684; called by muse, mutect2, varscan2
- NBEAL2 | c.1188dup p.S397Lfs*7 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | catalogued as rs1259251993; called by mutect2, pindel, varscan2
- NDUFA3 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.832); catalogued as rs769564432, COSV52927479; called by muse, mutect2, varscan2
- NECTIN3 | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as COSV60551050; called by muse, mutect2, varscan2
- NECTIN4 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63512533; called by muse, mutect2, varscan2
- NLN | c.845A>G p.Q282R | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV66765717; called by muse, mutect2, varscan2
- NLRC5 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 22/118 reads (19%) | catalogued as COSV52654303; called by muse, varscan2
- NLRC5 | c.1394T>C p.L465P | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV52654311; called by muse, varscan2
- NOC2L | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs372047419; called by muse, mutect2, varscan2
- NOTCH1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); catalogued as rs528033027, COSV53036690, COSV53091911, COSV99486695; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | catalogued as rs776154715; called by mutect2, varscan2
- NTNG1 | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV53969634; called by muse, mutect2, varscan2
- NUP107 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs1451167341, COSV57494492; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 24/171 reads (14%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NXF3 | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 170/511 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV67703373; called by muse, mutect2, varscan2
- OR10R2 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 25/443 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63768779; called by muse, mutect2
- OR2T12 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs574756693, COSV58777414; called by mutect2, varscan2
- OR2T6 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63216133; called by muse, mutect2, varscan2
- OR4C46 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 75/250 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as rs1346328521, COSV60219124; called by muse, mutect2, varscan2
- OR52B4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV68768844; called by muse, mutect2, varscan2
- OR5C1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs770972890, COSV65455871; called by muse, mutect2, varscan2
- P2RY6 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 110/271 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs754852770, COSV62936451; called by muse, mutect2, varscan2
- PAF1 | c.741-1G>A p.X247_splice | Splice Site (SNP) | VAF 36/131 reads (27%) | catalogued as COSV55393636; called by muse, mutect2, varscan2
- PAM | c.1298del p.K433Rfs*32 | Frame Shift Del (DEL) | VAF 39/141 reads (28%) | catalogued as rs1235994663; called by mutect2, pindel, varscan2
- PAPPA | c.1896C>G p.Y632* | Nonsense Mutation (SNP) | VAF 120/408 reads (29%) | catalogued as COSV60282199; called by muse, mutect2, varscan2
- PARP2 | c.448A>G p.R150G | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51637607, COSV51638856; called by muse, mutect2, varscan2
- PCDH9 | c.1523T>C p.L508P | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60546244; called by muse, mutect2, varscan2
- PCDHAC1 | c.1626C>A p.N542K | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV53847582; called by muse, mutect2, varscan2
- PCDHB16 | c.335A>C p.N112T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV53361549; called by muse, mutect2, varscan2
- PDLIM4 | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.069); catalogued as COSV53803954, COSV99516804; called by muse, mutect2, varscan2
- PIK3CD | c.2911G>A p.G971R | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750392184, COSV63128359; called by muse, mutect2, varscan2
- PITPNM2 | c.717G>T p.M239I | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54899995; called by muse, mutect2, varscan2
- PKD1 | c.2764C>A p.L922I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.308); catalogued as rs1290050535, COSV51915064; called by muse, mutect2, varscan2
- PLAG1 | c.1373del p.P458Hfs*13 | Frame Shift Del (DEL) | VAF 26/259 reads (10%) | catalogued as COSV57610471; called by mutect2, pindel, varscan2
- PLEC | c.3388C>T p.R1130W (on ENST00000322810 / NM_201380.4; = p.R1020W on NM_000445.5) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs373993300; called by muse, mutect2
- PLIN3 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV55735151; called by muse, mutect2, varscan2
- PLXND1 | c.4361G>A p.G1454D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); catalogued as COSV60712735; called by muse, mutect2, varscan2
- PNCK | c.112G>A p.A38T (on ENST00000340888 / NM_001366975.1; = p.A121T on NM_001039582.3) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs144452893, COSV61743623; called by muse, mutect2, varscan2
- POM121L12 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV68692829; called by muse, mutect2, varscan2
- POMGNT1 | c.610C>A p.L204M | Missense Mutation (SNP) | VAF 98/320 reads (31%) | PolyPhen probably damaging (0.938); catalogued as COSV64339794; called by muse, varscan2
- POU4F1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV65884214; called by muse, mutect2, varscan2
- POU4F2 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs777381197, COSV55584036; called by muse, mutect2, varscan2
- PPP2R5D | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV57839897; called by muse, mutect2, varscan2
- PPP3CA | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV59919811; called by muse, mutect2, varscan2
- PQBP1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.236); catalogued as rs1370647444, COSV54430227; called by muse, mutect2, varscan2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs764112302; called by mutect2, varscan2
- PRF1 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as rs150628656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKDC | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs773506987, COSV58050671; called by muse, mutect2, varscan2
- PRR12 | c.1525C>T p.P509S (on ENST00000615927; = p.P1330S on NM_020719.3) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs888826847, COSV69817478; called by muse, mutect2
- PRRC2C | c.8126A>G p.Y2709C (on ENST00000367742; = p.Y2707C on NM_015172.4) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58904635; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PTGR2 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99966487; called by muse, mutect2
- PYGM | c.493G>T p.G165W | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51216341; called by muse, mutect2, varscan2
- R3HDM4 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV64293053; called by muse, mutect2, varscan2
- RAB40C | c.811dup p.Q271Pfs*7 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | catalogued as rs1555457247; called by mutect2, varscan2
- RAD23A | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.166); catalogued as rs977516182, COSV57120837; called by muse, mutect2
- RASAL2 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440295041, COSV62711982; called by muse, mutect2, varscan2
- RBM15B | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60042536; called by muse, mutect2, varscan2
- RBMS2 | c.60_62del p.N20del | In Frame Del (DEL) | VAF 42/180 reads (23%) | catalogued as rs781172723; called by pindel, varscan2
- RBPMS | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55122733; called by muse, mutect2, varscan2
- RERE | c.4264G>A p.V1422M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs529548316, CM145520, COSV61941401; called by muse, mutect2, varscan2
- REV1 | c.2699C>T p.T900I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV51484547; called by muse, mutect2, varscan2
- RGMA | c.1300C>G p.P434A | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1230832575, COSV100224292; called by muse, mutect2, varscan2
- RIBC1 | c.1061A>G p.Q354R | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.559); catalogued as COSV51447939; called by muse, mutect2, varscan2
- RICTOR | c.4627C>T p.H1543Y | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV57121242; called by muse, mutect2, varscan2
- RIMBP2 | c.3037T>A p.F1013I | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55466023, COSV55470989, COSV55480263; called by muse, mutect2
- RIOX2 | c.629G>A p.S210N | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.172); catalogued as COSV57724128; called by muse, mutect2, varscan2
- RNF126 | c.608del p.P203Hfs*21 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs1414482648; called by mutect2, pindel
- RNF13 | c.829del p.T277Pfs*29 | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | catalogued as rs1559980566; called by mutect2, pindel, varscan2
- RNF216 | c.450G>T p.E150D (on ENST00000425013 / NM_207116.3; = p.E207D on NM_207111.4) | Missense Mutation (SNP) | VAF 118/355 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs958623853, COSV66290236; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 76/152 reads (50%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RNGTT | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55649933, COSV99667480; called by muse, mutect2
- RP9 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51806836; called by muse, mutect2, varscan2
- SALL3 | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs746622657, COSV73305811; called by muse, mutect2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 34/115 reads (30%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SAMD4B | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58751297; called by muse, mutect2, varscan2
- SAMD7 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs752085492, COSV59417528; called by muse, mutect2, varscan2
- SAMHD1 | c.1265T>C p.L422P | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53429371; called by muse, mutect2, varscan2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | catalogued as rs771002611; called by mutect2, pindel, varscan2
- SDC4 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs145789563; called by muse, mutect2, varscan2
- SEMA3D | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52390763; called by muse, mutect2, varscan2
- SEMA4C | c.2032G>C p.V678L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV59690515; called by muse, mutect2, varscan2
- SHANK1 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.441); catalogued as COSV53249089; called by muse, mutect2
- SHISA3 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59979812; called by muse, mutect2
- SIL1 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs375241132; called by muse, mutect2, varscan2
- SLC17A3 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57759872; called by muse, mutect2, varscan2
- SLC17A3 | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1260744833, COSV57759879; called by muse, mutect2, varscan2
- SLC1A4 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV52234350; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs749849908; called by mutect2, pindel
- SLC27A3 | c.1915A>G p.K639E (on ENST00000271857; = p.K511E on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55163381; called by muse, mutect2, varscan2
- SLC38A3 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs780477983, COSV68843988; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC44A4 | c.1454T>C p.F485S | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV57667006; called by muse, mutect2, varscan2
- SLC9A5 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV55361738; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2048G>T p.G683V (on ENST00000540229 / NM_001371097.1; = p.G622V on NM_001009562.4) | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1028101721, COSV67443300; called by muse, mutect2, varscan2
- SLITRK2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV59422694; called by muse, mutect2, varscan2
- SLITRK5 | c.1143C>A p.N381K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV61522565; called by muse, mutect2, varscan2
- SLX4 | c.1406del p.P469Hfs*4 | Frame Shift Del (DEL) | VAF 42/204 reads (21%) | catalogued as rs774532876; called by mutect2, pindel, varscan2
- SMC1B | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV61581466; called by muse, mutect2, varscan2
- SNAI3 | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.19); catalogued as COSV60002704; called by muse, mutect2, varscan2
- SNRPA | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as rs771537539, COSV54681006, COSV99698857; called by mutect2, varscan2
- SOAT1 | c.533T>A p.F178Y | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62653917; called by muse, mutect2
- SOHLH2 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369483625; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 127/204 reads (62%) | catalogued as rs1278336874; called by mutect2, varscan2
- SOX7 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV58730713; called by muse, mutect2, varscan2
- SPDYE3 | c.1612C>T p.H538Y | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.782); catalogued as rs767238582, COSV60107139; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 53/142 reads (37%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPTBN1 | c.4619G>A p.R1540H | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1284166106, COSV61686618; called by muse, mutect2, varscan2
- SPTBN1 | c.5579T>G p.V1860G | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61688090; called by muse, mutect2, varscan2
- SRP72 | c.1785G>T p.K595N | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV61377587; called by muse, mutect2, varscan2
- SSTR1 | c.683T>C p.F228S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.531); catalogued as COSV57455755; called by muse, mutect2, varscan2
- ST3GAL2 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 66/201 reads (33%) | PolyPhen probably damaging (1); catalogued as COSV61596542; called by muse, mutect2, varscan2
- STK11IP | c.2785del p.Q929Sfs*39 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | catalogued as rs1559188516; called by mutect2, pindel, varscan2
- SVIL | c.4229C>T p.A1410V (on ENST00000355867 / NM_021738.3; = p.A984V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750828170, COSV63442854; called by muse, mutect2, varscan2
- SVIL | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63442867; called by muse, mutect2, varscan2
- SYNM | c.4040G>A p.G1347D | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV50441622; called by muse, mutect2, varscan2
- SYNPO2L | c.2624C>A p.A875D (on ENST00000394810 / NM_001114133.3; = p.A651D on NM_024875.5) | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV65736793, COSV65738426; called by muse, mutect2
- SYVN1 | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV53695236; called by muse, mutect2, varscan2
- TACC2 | c.5353A>G p.I1785V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57754092; called by muse, mutect2
- TASOR | c.4187C>T p.A1396V (on ENST00000355628 / NM_001365636.2; = p.A1020V on NM_015224.3) | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV58303454; called by muse, mutect2, varscan2
- TASP1 | c.626T>C p.V209A | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs112168352, COSV61812804, COSV61816298; called by muse, mutect2, varscan2
- TBC1D2 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59784674; called by muse, mutect2, varscan2
- TBX18 | c.1691C>T p.T564M | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs1416893079, COSV63735937; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TCHH | c.3989G>A p.R1330H | Missense Mutation (SNP) | VAF 103/361 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as COSV64274475; called by muse, mutect2, varscan2
- TCIRG1 | c.2381T>G p.L794R | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55835311; called by muse, mutect2, varscan2
- TCTN2 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1175909058, COSV57632715; called by muse, mutect2
- TECTA | c.924A>C p.K308N | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.416); catalogued as COSV50703550; called by muse, mutect2, varscan2
- TESK1 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs377480721; called by muse, mutect2, varscan2
- TFAP2B | c.1061A>C p.K354T | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53827311; called by muse, mutect2, varscan2
- TG | c.746-2A>G p.X249_splice | Splice Site (SNP) | VAF 133/412 reads (32%) | catalogued as rs1271393370, COSV55073995; called by muse, mutect2, varscan2
- TGFBR2 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV55448796; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs139792932, COSV99305007; called by muse, mutect2, varscan2
- THOP1 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs571489169, COSV57018538; called by muse, mutect2
- TICAM1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); catalogued as COSV50231862; called by muse, mutect2, varscan2
- TMC2 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV62652266; called by muse, mutect2, varscan2
- TMCC2 | c.1145A>C p.Q382P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV58002894; called by muse, mutect2, varscan2
- TMEM131 | c.4244A>G p.D1415G | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV51774806; called by muse, mutect2, varscan2
- TMEM132D | c.2284G>T p.G762* | Nonsense Mutation (SNP) | VAF 33/140 reads (24%) | catalogued as COSV67160107; called by muse, mutect2, varscan2
- TMEM174 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 109/376 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs748138300, COSV57113604; called by muse, mutect2, varscan2
- TMEM204 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.103); catalogued as COSV54152502; called by muse, mutect2, varscan2
- TMEM255B | c.969del p.Y324Tfs*9 | Frame Shift Del (DEL) | VAF 72/271 reads (27%) | catalogued as COSV100944145; called by mutect2, pindel, varscan2
- TMEM259 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52259910; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 35/80 reads (44%) | catalogued as rs781830688; called by mutect2, varscan2
- TNFAIP6 | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.326); catalogued as COSV54640648; called by muse, varscan2
- TNN | c.1910C>T p.T637M | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs144603425; called by muse, mutect2, varscan2
- TNRC6C | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 123/382 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs771723841, COSV56944240; called by muse, mutect2, varscan2
- TOR2A | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376074923; called by muse, mutect2, varscan2
- TRAF7 | c.1606G>A p.G536S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58212589; called by muse, mutect2, varscan2
- TRHDE | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV53842147; called by muse, mutect2, varscan2
- TRMT11 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs142681128, COSV57672784; called by muse, mutect2, varscan2
- TSC22D3 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59777681; called by muse, mutect2, varscan2
- TSGA13 | c.452del p.K151Sfs*2 | Frame Shift Del (DEL) | VAF 29/101 reads (29%) | catalogued as rs782528606, COSV58404193; called by mutect2, varscan2
- TSHZ2 | c.2454dup p.M819Hfs*11 | Frame Shift Ins (INS) | VAF 39/121 reads (32%) | catalogued as rs1193207010; called by mutect2, varscan2
- TSKS | c.1748del p.P583Qfs*? | Frame Shift Del (DEL) | VAF 50/170 reads (29%) | catalogued as rs749002253, COSV55877613; called by mutect2, varscan2
- TSTD2 | c.1102C>A p.L368I | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV52247099; called by muse, mutect2, varscan2
- TTBK1 | c.2741G>A p.G914E | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.127); catalogued as COSV52490732; called by muse, mutect2, varscan2
- TTC21A | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs760939060, COSV56187947; called by muse, mutect2, varscan2
- TTN | c.78545C>A p.T26182N (on ENST00000591111; = p.T18758N on NM_003319.4) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | PolyPhen benign (0); catalogued as COSV60018597; called by muse, mutect2, varscan2
- TTN | c.22986T>C p.S7662= (on ENST00000591111; = p.S6735= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 11/256 reads (4%) | catalogued as COSV60018641; called by muse, mutect2
- TUBGCP6 | c.5189C>T p.A1730V | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764792112, COSV50542883; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | catalogued as rs760251146; called by mutect2, varscan2
- TXLNB | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as rs761996834, COSV64443864; called by muse, mutect2, varscan2
- TYW5 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63562198; called by muse, mutect2, varscan2
- UGT2A3 | c.342del p.F114Lfs*4 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs763425928; called by mutect2, varscan2
- ULK4 | c.3206T>C p.M1069T | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV57207106; called by muse, mutect2, varscan2
- UNC13B | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as rs750849094, COSV65934135; called by muse, varscan2
- UNC5B | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 85/303 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751397139, COSV58976491; called by muse, mutect2, varscan2
- UNC79 | c.628T>C p.S210P (on ENST00000393151 / NM_001346218.2; = p.S33P on NM_020818.5) | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); catalogued as COSV56384882; called by muse, mutect2, varscan2
- UPK2 | c.150del p.C51Vfs*10 | Frame Shift Del (DEL) | VAF 19/93 reads (20%) | catalogued as rs750952264; called by mutect2, pindel, varscan2
- USP49 | c.1754G>T p.R585M | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as COSV51896699; called by muse, mutect2, varscan2
- UST | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.16); catalogued as COSV66547232; called by muse, mutect2
- VCAN | c.2533A>C p.S845R | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV54102912, COSV54103950; called by muse, mutect2, varscan2
- VEGFC | c.817A>C p.T273P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54597449; called by muse, mutect2
- WASF1 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55619538; called by muse, mutect2, varscan2
- WHRN | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as rs945712185, COSV54330198; called by muse, mutect2, varscan2
- WNK3 | c.4769G>T p.R1590I | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100670987, COSV63613517; called by muse, mutect2, varscan2
- WNT9A | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.348); catalogued as COSV55294334; called by muse, mutect2, varscan2
- WRAP73 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54561000; called by muse, mutect2, varscan2
- XAB2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV60697174; called by muse, mutect2, varscan2
- XIRP2 | c.3678A>C p.E1226D (on ENST00000628543; = p.E1401D on NM_152381.6) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54696788, COSV54722905, COSV99739657; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 56/176 reads (32%) | catalogued as rs762052135; called by mutect2, varscan2
- ZC3H11A | c.35del p.F12Sfs*20 | Frame Shift Del (DEL) | VAF 44/188 reads (23%) | catalogued as rs768425662; called by mutect2, varscan2
- ZC3H18 | c.942del p.A315Qfs*18 | Frame Shift Del (DEL) | VAF 80/290 reads (28%) | catalogued as COSV56322579; called by mutect2, pindel, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as rs745875253; called by mutect2, varscan2
- ZFHX4 | c.9730C>T p.Q3244* | Nonsense Mutation (SNP) | VAF 73/209 reads (35%) | catalogued as COSV50728608; called by muse, mutect2, varscan2
- ZFP91 | c.632A>T p.E211V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.098); catalogued as COSV60158578, COSV60161761; called by muse, mutect2, varscan2
- ZFYVE26 | c.5432C>T p.P1811L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1453291765, COSV61327689; called by muse, mutect2, varscan2
- ZMYM3 | c.1757del p.G586Afs*4 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as COSV100077374; called by mutect2, pindel, varscan2
- ZNF202 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV60246973; called by muse, mutect2, varscan2
- ZNF227 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.056); catalogued as COSV57312175; called by muse, mutect2, varscan2
- ZNF345 | c.904A>G p.T302A | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV59323847; called by muse, mutect2, varscan2
- ZNF556 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755425238, COSV56911927; called by muse, mutect2, varscan2
- ZNF559 | c.334A>G p.T112A | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV57835527; called by muse, mutect2
- ZNF561 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.531); catalogued as COSV57177634; called by muse, mutect2, varscan2
- ZNF564 | c.1318_1319del p.M440Dfs*10 | Frame Shift Del (DEL) | VAF 110/450 reads (24%) | catalogued as rs764089254; called by pindel, varscan2
- ZNF611 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV60540626; called by muse, mutect2, varscan2
- ZNF630 | c.159A>C p.K53N | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); catalogued as COSV52096181; called by muse, mutect2, varscan2
- ZNF648 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV60570660; called by muse, mutect2, varscan2
- ZNF808 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs573679515, COSV63119053; called by muse, mutect2, varscan2
- ZNRF3 | c.2575C>T p.R859* (on ENST00000544604 / NM_001206998.2; = p.R759* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as rs1457204359, COSV60433705; called by muse, mutect2, varscan2
- ZXDB | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV66492697; called by muse, mutect2, varscan2
- ACTN3 | c.1152dup p.L385Afs*9 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.432del p.E146Kfs*13 | Frame Shift Del (DEL) | VAF 41/129 reads (32%) | called by mutect2, pindel, varscan2
- ADM2 | c.159del p.A54Hfs*263 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- ALAS2 | c.50del p.G17Afs*6 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- ANK2 | c.8460del p.D2821Tfs*41 | Frame Shift Del (DEL) | VAF 21/180 reads (12%) | called by mutect2, pindel, varscan2
- ANK3 | c.832dup p.R278Kfs*16 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | called by mutect2, pindel
- APPL2 | c.1221del p.K407Nfs*11 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- ARHGAP5 | c.2476del p.R826Gfs*17 | Frame Shift Del (DEL) | VAF 18/147 reads (12%) | called by mutect2, pindel, varscan2
- ARHGEF5 | c.4540del p.Q1514Rfs*24 | Frame Shift Del (DEL) | VAF 39/323 reads (12%) | called by mutect2, pindel, varscan2
- ATRAID | c.306del p.V103Wfs*11 (on ENST00000611786; = p.V48Wfs*11 on NM_001170795.3) | Frame Shift Del (DEL) | VAF 21/200 reads (11%) | called by mutect2, pindel, varscan2
- ATXN1 | c.449del p.P150Qfs*38 | Frame Shift Del (DEL) | VAF 41/142 reads (29%) | called by mutect2, pindel, varscan2
- C10orf71 | c.353del p.P118Hfs*16 | Frame Shift Del (DEL) | VAF 21/197 reads (11%) | called by mutect2, pindel, varscan2
- C17orf75 | c.480del p.G161Dfs*16 | Frame Shift Del (DEL) | VAF 72/249 reads (29%) | called by mutect2, pindel, varscan2
- CATSPERB | c.2820del p.V941Ffs*34 | Frame Shift Del (DEL) | VAF 53/190 reads (28%) | called by mutect2, pindel, varscan2
- CCDC112 | c.1041_1043del p.R348del | In Frame Del (DEL) | VAF 50/176 reads (28%) | called by mutect2, pindel, varscan2
- CEP350 | c.8251dup p.I2751Nfs*29 | Frame Shift Ins (INS) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- CILK1 | c.1031del p.P344Lfs*42 (on ENST00000350082 / NM_001375397.1; = p.P344Lfs*54 on NM_014920.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 41/160 reads (26%) | called by mutect2, pindel, varscan2
- CPSF1 | c.3208del p.Q1070Sfs*31 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- DDX17 | c.488del p.G163Efs*20 | Frame Shift Del (DEL) | VAF 53/176 reads (30%) | called by mutect2, pindel, varscan2
- DENND2A | c.1271del p.F424Sfs*18 | Frame Shift Del (DEL) | VAF 86/295 reads (29%) | called by mutect2, pindel, varscan2
- DENND5A | c.2903del p.G968Afs*29 | Frame Shift Del (DEL) | VAF 150/590 reads (25%) | called by pindel, varscan2
- DMD | c.10027del p.S3343Lfs*34 | Frame Shift Del (DEL) | VAF 48/178 reads (27%) | called by mutect2, pindel, varscan2
- DNAJC5 | c.456del p.E153Rfs*68 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.247del p.Q83Nfs*43 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- F3 | c.537del p.F179Lfs*5 | Frame Shift Del (DEL) | VAF 9/102 reads (9%) | called by mutect2, pindel
- FBXO21 | c.505del p.I169Ffs*11 | Frame Shift Del (DEL) | VAF 36/114 reads (32%) | called by mutect2, varscan2
- GBP7 | c.1293del p.H432Tfs*5 | Frame Shift Del (DEL) | VAF 64/228 reads (28%) | called by mutect2, varscan2
- GLI2 | c.355del p.H119Tfs*4 | Frame Shift Del (DEL) | VAF 40/156 reads (26%) | called by mutect2, pindel, varscan2
- GLUD1 | c.112G>C p.A38P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.636); called by muse, varscan2
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 65/239 reads (27%) | called by mutect2, pindel, varscan2
- HOXB3 | c.1067del p.G356Afs*73 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- IFT88 | c.1358del p.K453Rfs*5 (on ENST00000319980 / NM_001318493.2; = p.K444Rfs*5 on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel
- INF2 | c.1587del p.V530Wfs*28 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- ITGA3 | c.2073dup p.G692Rfs*6 | Frame Shift Ins (INS) | VAF 34/123 reads (28%) | called by mutect2, pindel, varscan2
- ITGA7 | c.3454del p.R1152Gfs*115 (on ENST00000555728; = p.R1108Gfs*115 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- IWS1 | c.2404del p.S802Afs*7 | Frame Shift Del (DEL) | VAF 17/157 reads (11%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.1228del p.R410Efs*56 | Frame Shift Del (DEL) | VAF 44/151 reads (29%) | called by mutect2, pindel, varscan2
- KIF3A | c.1264dup p.M422Nfs*6 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- LCOR | c.697del p.M233Wfs*13 | Frame Shift Del (DEL) | VAF 27/110 reads (25%) | called by mutect2, pindel, varscan2
- LRBA | c.2808del p.F936Lfs*12 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- MCPH1 | c.1402del p.T468Pfs*32 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | called by mutect2, pindel, varscan2
- MGA | c.2287del p.W763Gfs*54 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- MGA | c.7704dup p.K2569Efs*54 (on ENST00000219905 / NM_001164273.1; = p.K2360Efs*54 on NM_001080541.2) | Frame Shift Ins (INS) | VAF 28/139 reads (20%) | called by mutect2, pindel, varscan2
- MIER3 | c.360_361del p.Q121Vfs*5 | Frame Shift Del (DEL) | VAF 49/143 reads (34%) | called by mutect2, pindel, varscan2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- MS4A8 | c.530del p.G177Vfs*2 | Frame Shift Del (DEL) | VAF 12/105 reads (11%) | called by mutect2, pindel, varscan2
- MTA1 | c.1913del p.G638Afs*11 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- MTREX | c.2475del p.A826Hfs*5 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, varscan2
- MYCL | c.120del p.T41Rfs*69 (on ENST00000372816 / NM_001033081.3; = p.T71Rfs*69 on NM_005376.5) | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- MYH6 | c.464_466del p.F155del | In Frame Del (DEL) | VAF 30/140 reads (21%) | called by pindel, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 110/429 reads (26%) | called by mutect2, pindel, varscan2
- NOL6 | c.1916del p.G639Afs*10 | Frame Shift Del (DEL) | VAF 136/442 reads (31%) | called by mutect2, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- OR5T3 | c.132del p.F44Lfs*8 | Frame Shift Del (DEL) | VAF 25/105 reads (24%) | called by mutect2, pindel, varscan2
- PLAC8 | c.242del p.P81Lfs*38 | Frame Shift Del (DEL) | VAF 45/169 reads (27%) | called by mutect2, pindel, varscan2
- PPP1R9A | c.81del p.Q28Rfs*3 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- PRKDC | c.1738del p.D580Ifs*23 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | called by mutect2, varscan2
- PRRC2C | c.4891del p.R1631Efs*31 (on ENST00000367742; = p.R1629Efs*31 on NM_015172.4) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- R3HDM2 | c.2257del p.Q753Rfs*6 | Frame Shift Del (DEL) | VAF 37/177 reads (21%) | called by mutect2, pindel, varscan2
- RNF111 | c.2318del p.P773Hfs*44 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel
- RNF168 | c.1169dup p.N390Kfs*7 | Frame Shift Ins (INS) | VAF 59/210 reads (28%) | called by mutect2, pindel, varscan2
- ROBO4 | c.2561del p.G854Efs*20 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- RPS6KA6 | c.1837del p.Y613Tfs*25 | Frame Shift Del (DEL) | VAF 67/251 reads (27%) | called by mutect2, pindel, varscan2
- SBNO1 | c.3416dup p.N1139Kfs*5 (on ENST00000420886; = p.N1138Kfs*5 on NM_018183.5) | Frame Shift Ins (INS) | VAF 71/172 reads (41%) | called by mutect2, varscan2
- SDSL | c.285dup p.E96Rfs*48 | Frame Shift Ins (INS) | VAF 19/102 reads (19%) | called by mutect2, pindel, varscan2
- SEMA4C | c.2276del p.P759Lfs*36 | Frame Shift Del (DEL) | VAF 38/120 reads (32%) | called by mutect2, pindel
- SLCO5A1 | c.1485del p.K495Nfs*2 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | called by mutect2, pindel, varscan2
- SOAT1 | c.195del p.F65Lfs*2 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- SOCS7 | c.1301G>A p.S434N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- STAMBPL1 | c.1222del p.H408Ifs*18 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- TAP1 | c.546del p.S184Pfs*54 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- TCEAL6 | c.23dup p.N8Kfs*2 | Frame Shift Ins (INS) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- TENM3 | c.3758del p.N1253Mfs*32 | Frame Shift Del (DEL) | VAF 38/100 reads (38%) | called by mutect2, pindel, varscan2
- TM6SF1 | c.1007del p.L336* | Frame Shift Del (DEL) | VAF 77/213 reads (36%) | called by mutect2, pindel, varscan2
- TMEM168 | c.690dup p.I231Yfs*6 | Frame Shift Ins (INS) | VAF 38/150 reads (25%) | called by mutect2, varscan2
- TSHZ3 | c.2701dup p.Q901Pfs*79 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- TTC31 | c.554del p.K185Rfs*74 | Frame Shift Del (DEL) | VAF 58/192 reads (30%) | called by mutect2, pindel, varscan2
- VPS45 | c.229dup p.X77_splice | Splice Site (INS) | VAF 26/110 reads (24%) | called by mutect2, pindel, varscan2
- YBX2 | c.677del p.P226Hfs*22 | Frame Shift Del (DEL) | VAF 78/306 reads (25%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2111del p.P704Qfs*31 (on ENST00000474710 / NM_001164342.2; = p.P631Qfs*31 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | called by mutect2, pindel, varscan2
- ZFP3 | c.1128del p.N377Tfs*170 | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | called by mutect2, pindel, varscan2
- ZNF366 | c.1170del p.I391Sfs*22 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- ZSCAN5B | c.1004dup p.G336Rfs*23 | Frame Shift Ins (INS) | VAF 45/197 reads (23%) | called by mutect2, pindel, varscan2
- ZZZ3 | c.2280_2282del p.D761del | In Frame Del (DEL) | VAF 22/168 reads (13%) | called by pindel, varscan2
- A2M | c.2364C>A p.A788= | Silent (SNP) | VAF 51/161 reads (32%) | catalogued as COSV100588552, COSV59385764; called by muse, mutect2, varscan2
- ABR | c.2160G>A p.T720= (on ENST00000302538 / NM_021962.5; = p.T683= on NM_001092.5) | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as rs752086857, COSV52145082; called by muse, mutect2, varscan2
- ACSF3 | c.609T>C p.S203= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV58078129; called by muse, mutect2, varscan2
- ACTL7B | c.1074G>A p.E358= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV65927279; called by muse, mutect2, varscan2
- ADAMTS17 | c.1947C>T p.A649= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs767077707, COSV51478960; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY8 | c.1044A>G p.Q348= | Silent (SNP) | VAF 63/237 reads (27%) | catalogued as rs758286510, COSV53905714; called by muse, mutect2, varscan2
- AFF2 | c.1785A>G p.K595= | Silent (SNP) | VAF 84/294 reads (29%) | catalogued as COSV53987304, COSV99661569; called by muse, mutect2, varscan2
- AKT3 | c.642C>A p.S214= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV55609077, COSV55615064; called by muse, mutect2, varscan2
- ANKRD16 | c.1038A>G p.P346= | Silent (SNP) | VAF 126/371 reads (34%) | catalogued as COSV51947326; called by muse, mutect2, varscan2
- ANKS4B | c.985C>T p.L329= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV61139100; called by muse, mutect2, varscan2
- ARHGAP31 | c.1497C>T p.S499= | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as rs752447673, COSV51792279; called by muse, mutect2, varscan2
- ARL10 | c.543C>T p.V181= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV59990535; called by muse, mutect2
- ATP6V0A4 | c.2412C>T p.H804= | Silent (SNP) | VAF 53/472 reads (11%) | catalogued as rs372230422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRNL1 | c.2886T>C p.N962= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV58085615; called by muse, mutect2, varscan2
- BRDT | c.1113G>A p.T371= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs745926830, COSV62864669; called by muse, mutect2
- BTAF1 | c.4989T>C p.D1663= | Silent (SNP) | VAF 69/199 reads (35%) | catalogued as COSV56433038; called by muse, mutect2, varscan2
- C2CD3 | c.5808C>T p.S1936= | Silent (SNP) | VAF 64/214 reads (30%) | catalogued as COSV58092750; called by muse, mutect2, varscan2
- CAPN2 | c.1722C>T p.I574= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs778542593, COSV54335834; called by muse, mutect2, varscan2
- CCDC138 | c.519T>C p.L173= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs1464127920, COSV54566618; called by muse, mutect2, varscan2
- CCNA1 | c.855A>G p.K285= | Silent (SNP) | VAF 50/202 reads (25%) | catalogued as COSV55221184; called by muse, varscan2
- CD27 | c.9G>A p.R3= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV56950072; called by muse, mutect2, varscan2
- CD69 | c.345A>G p.E115= | Silent (SNP) | VAF 51/158 reads (32%) | catalogued as COSV57302689; called by muse, varscan2
- CEP164 | c.2049A>T p.A683= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV54040623; called by muse, mutect2, varscan2
- CFAP47 | c.5169T>C p.N1723= | Silent (SNP) | VAF 83/269 reads (31%) | catalogued as COSV57973532; called by muse, mutect2, varscan2
- CLEC3B | c.243C>T p.C81= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV56109352, COSV56109695; called by muse, mutect2, varscan2
- COL11A1 | c.4026T>G p.G1342= | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as COSV62181813; called by muse, mutect2, varscan2
- COL4A3 | c.2016A>G p.P672= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV67415206; called by muse, mutect2, varscan2
- COL5A1 | c.2694C>T p.G898= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs139394549; called by muse, mutect2, varscan2
- CTNNA2 | c.2337T>G p.L779= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as COSV58149787; called by muse, mutect2, varscan2
- DCAF12L1 | c.234C>T p.Y78= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs767130770, COSV100948202, COSV64421700; called by muse, mutect2, varscan2
- DGKH | c.276C>T p.R92= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV54931414; called by muse, mutect2, varscan2
- DHX33 | c.735C>T p.G245= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as rs927313452, COSV56578789; called by muse, mutect2
- DMBT1 | c.612C>A p.A204= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV57542192; called by muse, mutect2, varscan2
- DOCK1 | c.2760C>A p.S920= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV54738169; called by muse, mutect2, varscan2
- DOCK3 | c.4147C>T p.L1383= | Silent (SNP) | VAF 27/207 reads (13%) | catalogued as COSV56518229; called by muse, mutect2, varscan2
- DPH7 | c.1164C>T p.G388= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV53021979; called by muse, mutect2, varscan2
- DRP2 | c.2448A>G p.A816= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101235178; called by muse, mutect2, varscan2
- ELOA2 | c.1353G>A p.P451= | Silent (SNP) | VAF 53/158 reads (34%) | catalogued as rs1331266584, COSV55294008; called by muse, mutect2, varscan2
- EP400 | c.2220T>G p.T740= | Silent (SNP) | VAF 9/216 reads (4%) | catalogued as COSV57770640; called by muse, mutect2
- EP400 | c.5019C>T p.G1673= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs762022153, COSV57770653; called by muse, mutect2, varscan2
- EPHA8 | c.474C>T p.D158= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs1305512765, COSV51267178; called by muse, mutect2, varscan2
- ERBB3 | c.1017C>T p.R339= | Silent (SNP) | VAF 77/210 reads (37%) | catalogued as COSV57252114; called by muse, mutect2, varscan2
- FANCD2 | c.69C>T p.T23= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV55036868; called by muse, mutect2, varscan2
- FGD1 | c.159C>T p.G53= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1329810583, COSV64308578; called by mutect2, varscan2
- FKBP10 | c.561C>T p.D187= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs782502878, COSV58636413; called by muse, mutect2, varscan2
- FKBP1B | c.234C>A p.T78= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV51980704; called by muse, mutect2, varscan2
- FLNB | c.6489C>T p.G2163= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs746887183, COSV55878134; called by muse, mutect2, varscan2
- FMNL1 | c.2635C>T p.L879= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as rs777203363, COSV58956699; called by muse, mutect2, varscan2
- GABRG1 | c.186A>C p.G62= | Silent (SNP) | VAF 17/247 reads (7%) | catalogued as COSV54953289; called by muse, mutect2
- GRID1 | c.1947A>G p.T649= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV60025943; called by muse, mutect2, varscan2
- GSTO2 | c.724C>T p.L242= | Silent (SNP) | VAF 19/181 reads (10%) | catalogued as COSV58538346; called by muse, mutect2, varscan2
- HEATR1 | c.1788A>G p.S596= | Silent (SNP) | VAF 53/157 reads (34%) | catalogued as COSV63980903; called by muse, mutect2, varscan2
- HERC2 | c.5370C>T p.L1790= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs1426712357, COSV55321228; called by muse, mutect2, varscan2
- HIF3A | c.810C>A p.I270= (on ENST00000377670 / NM_152795.4; = p.I201= on NM_022462.4) | Silent (SNP) | VAF 67/191 reads (35%) | catalogued as COSV52197877; called by muse, mutect2, varscan2
- HLA-DOA | c.270C>T p.A90= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs763052930, COSV57714056; called by muse, mutect2, varscan2
- HOXD12 | c.777C>T p.R259= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV66832562; called by muse, mutect2, varscan2
- IGLV7-46 | c.90T>G p.T30= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- INCENP | c.2424G>A p.P808= (on ENST00000394818 / NM_001040694.2; = p.P804= on NM_020238.3) | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as rs781137679, COSV53915224; called by muse, mutect2, varscan2
- IQCA1 | c.1750C>T p.L584= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as COSV54500850; called by muse, mutect2, varscan2
- ITPR3 | c.1206T>C p.N402= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV65408497; called by muse, mutect2, varscan2
- KLHL4 | c.1536T>C p.H512= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV64141779, COSV64148492; called by muse, mutect2, varscan2
- LAD1 | c.69G>A p.E23= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs374615719; called by muse, mutect2, varscan2
- LRIG1 | c.2676C>T p.C892= | Silent (SNP) | VAF 65/168 reads (39%) | catalogued as COSV56239468; called by muse, mutect2, varscan2
- LRIT2 | c.1470C>T p.C490= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV60561818; called by muse, mutect2
- MAN2C1 | c.2220C>T p.D740= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs376793963, COSV51226590; called by muse, mutect2, varscan2
- MANSC1 | c.306C>T p.N102= | Silent (SNP) | VAF 84/241 reads (35%) | catalogued as rs147279934; called by muse, mutect2, varscan2
- MFAP3L | c.1134A>G p.V378= | Silent (SNP) | VAF 51/162 reads (31%) | catalogued as rs760193902, COSV64372139; called by muse, mutect2, varscan2
- MLLT10 | c.2430C>T p.N810= (on ENST00000307729 / NM_001195626.3; = p.N826= on NM_004641.3) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV56995115; called by muse, mutect2, varscan2
- MPDZ | c.3084C>A p.G1028= | Silent (SNP) | VAF 84/288 reads (29%) | catalogued as COSV59917413; called by muse, mutect2, varscan2
- MSC | c.120G>A p.S40= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs563563444, COSV57696584; called by muse, mutect2, varscan2
- MYO10 | c.3759C>T p.S1253= | Silent (SNP) | VAF 86/241 reads (36%) | catalogued as rs749891318, COSV57020702; called by muse, mutect2, varscan2
- MYRIP | c.321C>T p.C107= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV56867932; called by muse, mutect2, varscan2
- NACC2 | c.462C>T p.A154= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- NCAM2 | c.2463T>C p.I821= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV53071802; called by muse, mutect2
- NCKAP1 | c.3094T>C p.L1032= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as COSV62940907; called by muse, mutect2, varscan2
- NEDD9 | c.1056G>A p.P352= | Silent (SNP) | VAF 62/167 reads (37%) | catalogued as rs575153183, COSV65220732; called by muse, mutect2, varscan2
- NEU2 | c.366G>A p.T122= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs762359314, COSV52092570; called by muse, mutect2, varscan2
- NODAL | c.834C>T p.G278= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1564667124, COSV54661063; called by muse, mutect2, varscan2
- NOTCH4 | c.3690C>T p.H1230= | Silent (SNP) | VAF 63/178 reads (35%) | catalogued as COSV66680424; called by muse, mutect2, varscan2
- NTRK1 | c.1366C>T p.L456= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as rs1044866618, COSV100693288; called by muse, varscan2
- OPTN | c.1275A>G p.E425= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as COSV53810582; called by muse, mutect2, varscan2
- ORC2 | c.1461T>C p.N487= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV52238355; called by muse, mutect2, varscan2
- PATL1 | c.1698T>C p.Y566= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV55688997; called by muse, mutect2, varscan2
- PDIA2 | c.1077C>A p.S359= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV51986657; called by muse, mutect2, varscan2
- PHKA2 | c.3453G>A p.S1151= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs747924699, COSV66053689; called by muse, mutect2, varscan2
- PIK3R4 | c.1689G>A p.R563= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV63240655; called by muse, mutect2, varscan2
- PLA2G4D | c.1230G>T p.R410= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV51820456; called by muse, mutect2, varscan2
- PLEC | c.13569C>G p.R4523= (on ENST00000322810 / NM_201380.4; = p.R4413= on NM_000445.5) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV59631001; called by muse, mutect2, varscan2
- PLXNA3 | c.4923C>T p.R1641= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs1268449346, COSV63753951; called by muse, mutect2, varscan2
- PNP | c.231C>A p.A77= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV64091932; called by muse, mutect2, varscan2
- POLA1 | c.1563G>A p.L521= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as COSV66885787; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1209C>T p.F403= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as rs1015986517, COSV53452532; called by muse, mutect2, varscan2
- PPP1R13L | c.2358C>T p.T786= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as COSV62908403; called by muse, mutect2, varscan2
- PPP1R3A | c.1209A>G p.Q403= | Silent (SNP) | VAF 74/288 reads (26%) | catalogued as COSV52881299, COSV52890881; called by muse, mutect2, varscan2
- PRDM4 | c.255A>G p.L85= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as COSV57305643; called by muse, mutect2, varscan2
- PRKAR2A | c.987C>T p.R329= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV55551859; called by muse, mutect2, varscan2
- PRSS22 | c.507C>G p.L169= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV50721550; called by muse, mutect2, varscan2
- PSPN | c.90C>T p.P30= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs1041607571, COSV55532162, COSV99831769; called by muse, mutect2, varscan2
- PTPRR | c.1155C>T p.D385= | Silent (SNP) | VAF 64/186 reads (34%) | catalogued as rs764441619, COSV51730742; called by muse, mutect2, varscan2
- PWWP2B | c.987G>A p.P329= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs372385259; called by muse, mutect2, varscan2
- RAB8B | c.453C>T p.S151= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs138589907; called by muse, mutect2, varscan2
- RASL11B | c.129C>T p.G43= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1205447573, COSV50535033; called by muse, mutect2, varscan2
- RBM42 | c.934C>T p.L312= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs779937122, COSV52896661; called by muse, mutect2, varscan2
- REEP4 | c.753G>A p.V251= | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as COSV57941812; called by muse, mutect2, varscan2
- REX1BD | c.291C>T p.F97= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100678980; called by muse, mutect2, varscan2
- ROPN1L | c.51G>A p.P17= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV56873658; called by muse, mutect2
- SH3GLB2 | c.1140C>T p.G380= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV65330794; called by muse, mutect2, varscan2
- SHISAL2A | c.438C>T p.S146= | Silent (SNP) | VAF 71/211 reads (34%) | catalogued as rs779249380, COSV68979727; called by muse, mutect2, varscan2
- SLC13A4 | c.801C>T p.C267= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as COSV62460880; called by muse, mutect2, varscan2
- SLC49A3 | c.1038C>A p.T346= (on ENST00000404286 / NM_001294341.2; = p.T345= on NM_032219.4) | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV100448416; called by muse, mutect2, varscan2
- SLC4A11 | c.1779A>G p.Q593= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV66261693; called by muse, mutect2, varscan2
- SLC4A5 | c.288G>A p.E96= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV61027134; called by muse, mutect2, varscan2
- SLC5A6 | c.96C>T p.F32= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs753660328, COSV60159261; called by muse, mutect2, varscan2
- SMURF1 | c.298C>T p.L100= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV63157226; called by muse, mutect2, varscan2
- SNX17 | c.1035C>T p.R345= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV52007558; called by muse, mutect2, varscan2
- SORBS2 | c.1044A>G p.S348= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV52998227; called by muse, mutect2, varscan2
- SOX9 | c.1260C>T p.Y420= | Silent (SNP) | VAF 72/262 reads (27%) | catalogued as COSV55423998, COSV55429926; called by muse, mutect2, varscan2
- SP100 | c.1110A>G p.E370= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV50978353; called by muse, mutect2
- SPRED2 | c.1188C>T p.P396= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs905192325, COSV62692631; called by muse, mutect2, varscan2
- STX3 | c.822G>A p.L274= | Silent (SNP) | VAF 53/192 reads (28%) | catalogued as COSV55697424; called by muse, mutect2, varscan2
- SUGP2 | c.2721C>T p.P907= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs748531989, COSV58257897; called by muse, mutect2, varscan2
- SVIL | c.1824C>T p.C608= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV63442860; called by muse, mutect2, varscan2
- TAX1BP1 | c.2313G>A p.Q771= | Silent (SNP) | VAF 72/252 reads (29%) | catalogued as COSV52236827; called by muse, varscan2
- TBX6 | c.1212G>A p.A404= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs561072265, COSV54220654, COSV54221283; called by muse, mutect2, varscan2
- TECTA | c.1332C>T p.Y444= | Silent (SNP) | VAF 213/720 reads (30%) | catalogued as rs775483215, COSV50697721; called by muse, mutect2, varscan2
- TMEM132D | c.2709G>T p.G903= | Silent (SNP) | VAF 52/161 reads (32%) | catalogued as COSV67160101; called by muse, mutect2, varscan2
- TMEM14B | c.105C>T p.S35= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs146042312; called by muse, mutect2
- TMEM63B | c.33C>A p.T11= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV52478453; called by muse, mutect2, varscan2
- TRBV4-1 | c.237G>T p.V79= | Silent (SNP) | VAF 83/216 reads (38%) | called by muse, mutect2, varscan2
- TTF1 | c.720G>A p.S240= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as rs143824332, COSV57507835; called by muse, mutect2, varscan2
- UBA6 | c.162A>G p.T54= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV59176681; called by muse, mutect2, varscan2
- USP42 | c.753A>G p.S251= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs546216572, COSV60359754; called by muse, mutect2, varscan2
- VCAN | c.714T>G p.T238= | Silent (SNP) | VAF 12/220 reads (5%) | catalogued as COSV54095802, COSV54096791; called by muse, mutect2
- VILL | c.186C>T p.Y62= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV52184330; called by muse, mutect2, varscan2
- VIM | c.459G>A p.E153= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV56405647, COSV56406915; called by muse, mutect2, varscan2
- WDR64 | c.1320G>A p.L440= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV63795391; called by muse, mutect2, varscan2
- ZAP70 | c.1221C>T p.A407= | Silent (SNP) | VAF 32/248 reads (13%) | catalogued as COSV53853973; called by muse, mutect2, varscan2
- ZBED4 | c.2973C>T p.S991= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99351037; called by muse, mutect2, varscan2
- ZC3H7B | c.771C>T p.D257= | Silent (SNP) | VAF 51/137 reads (37%) | catalogued as rs774206921, COSV60961686; called by muse, mutect2, varscan2
- ZNF142 | c.4770G>A p.R1590= (on ENST00000411696 / NM_001379660.1; = p.R1390= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV68743581; called by muse, mutect2, varscan2
- ZNF205 | c.1512C>T p.Y504= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs1260177735, COSV54620692; called by muse, mutect2, varscan2
- ZNF324 | c.507C>T p.P169= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as rs766315518, COSV52180555; called by muse, mutect2, varscan2
- ZNF324 | c.1269G>A p.K423= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs751592303, COSV52180567; called by muse, mutect2, varscan2
- ZNF555 | c.651G>A p.R217= | Silent (SNP) | VAF 52/153 reads (34%) | catalogued as COSV62073146; called by muse, mutect2, varscan2
- ZNF804A | c.2334T>A p.S778= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV56433517, COSV56446507; called by muse, mutect2, varscan2
- ZSCAN2 | c.1605C>T p.C535= | Silent (SNP) | VAF 73/224 reads (33%) | catalogued as rs370905881; called by muse, mutect2, varscan2
- AIRE | c.880-200del | Intron (DEL) | VAF 50/170 reads (29%) | catalogued as rs757773290, COSV99381230; called by mutect2, varscan2
- C14orf177 | n.588G>A | RNA (SNP) | VAF 9/38 reads (24%) | catalogued as COSV57900846; called by muse, mutect2, varscan2
- CASP2 | c.967+85G>T | Intron (SNP) | VAF 17/55 reads (31%) | catalogued as COSV60082317; called by muse, mutect2, varscan2
- CIT | c.2082+1866C>T | Intron (SNP) | VAF 13/105 reads (12%) | catalogued as rs753293581, COSV99949092; called by muse, mutect2, varscan2
- DDX41 | c.*638C>T | 3'UTR (SNP) | VAF 14/55 reads (25%) | catalogued as COSV57252020; called by muse, mutect2, varscan2
- DNM1L | c.*1579_*1593del | 3'UTR (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- ELMOD3 | c.943+159T>C | Intron (SNP) | VAF 85/251 reads (34%) | catalogued as rs748696602, COSV99809346; called by muse, mutect2, varscan2
- IGLL3P | n.271A>C | RNA (SNP) | VAF 24/252 reads (10%) | called by muse, mutect2
- MAGEC3 | c.1124-181C>T | Intron (SNP) | VAF 69/225 reads (31%) | catalogued as COSV100025157; called by muse, mutect2, varscan2
- MIR1303 | n.46_48del | RNA (DEL) | VAF 10/82 reads (12%) | catalogued as rs747084698; called by pindel, varscan2
- RUFY3 | chr4:70794826 del AAAG | 3'Flank (DEL) | VAF 55/172 reads (32%) | catalogued as rs866962400; called by pindel, varscan2
- RUNX2 | c.-10del | 5'UTR (DEL) | VAF 44/116 reads (38%) | catalogued as rs748951752; called by mutect2, varscan2
- SNORA22 | n.87A>G | RNA (SNP) | VAF 34/265 reads (13%) | catalogued as rs566226165; called by muse, mutect2, varscan2
- SYNE1 | c.24977-1784T>C | Intron (SNP) | VAF 18/88 reads (20%) | catalogued as COSV99558929; called by muse, mutect2
- SYTL2 | c.1615+1297C>T | Intron (SNP) | VAF 77/273 reads (28%) | catalogued as rs371312801; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3354del | Intron (DEL) | VAF 54/193 reads (28%) | catalogued as rs767992187; called by mutect2, pindel, varscan2
- XIRP2 | c.-96T>G | 5'UTR (SNP) | VAF 31/93 reads (33%) | catalogued as rs1008034648, COSV54696767; called by muse, mutect2, varscan2
- ZSWIM7 | c.76+16C>T | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as rs1449449941, COSV55422727; called by muse, mutect2, varscan2
